Somatic mutation profile of tumor specimen MP2PRT-PAVAUP-TMP1-A (aliquot MP2PRT-PAVAUP-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVAUP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.3 years (2,655 days).
Specimen MP2PRT-PAVAUP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28d4037c-a286-4dfd-9998-dbc205633395.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVAUP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVAUP-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f8f1f88-d7e4-4f18-bec9-109f5834f424

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Nonsense Mutation 2, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS14 | c.2860G>A p.G954R | Missense Mutation (SNP) | VAF 172/938 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs752215499; called by muse, mutect2, varscan2
- APBA1 | c.1828G>A p.V610M | Missense Mutation (SNP) | VAF 100/484 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs759823383; called by muse, mutect2, varscan2
- COL20A1 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 139/634 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as rs753031023, COSV58916083; called by muse, mutect2, varscan2
- DCXR | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 146/524 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs752090622; called by muse, mutect2, varscan2
- DZIP1 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 74/315 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201109671; called by muse, mutect2, varscan2
- FAM163A | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 170/746 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs145701153, COSV59205320; called by muse, mutect2, varscan2
- LHCGR | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 99/433 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.809); catalogued as rs149917479, COSV54297069; called by muse, mutect2, varscan2
- MFAP3L | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 86/493 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs184358631; called by muse, mutect2, varscan2
- NELL2 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 32/144 reads (22%) | catalogued as rs1435146157, COSV61578519, COSV61582190; called by muse, mutect2, varscan2
- SEC14L1 | c.1588G>A p.V530I | Missense Mutation (SNP) | VAF 72/456 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs774609620, COSV66723273; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 71/263 reads (27%) | called by muse, mutect2, varscan2
- PCDHA7 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 117/407 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKAG3 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 102/471 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- STT3B | c.1688C>G p.S563C | Missense Mutation (SNP) | VAF 83/339 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF217 | c.431dup p.I145Dfs*15 | Frame Shift Ins (INS) | VAF 87/384 reads (23%) | called by mutect2, pindel, varscan2
- ZNF316 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 212/820 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- DCAF8L2 | c.192C>T p.N64= | Silent (SNP) | VAF 151/410 reads (37%) | catalogued as rs990691409; called by muse, mutect2, varscan2
- ENAM | c.3096C>A p.G1032= | Silent (SNP) | VAF 88/507 reads (17%) | catalogued as COSV68537289; called by muse, mutect2, varscan2
- MAGEL2 | c.534G>A p.P178= | Silent (SNP) | VAF 269/1083 reads (25%) | catalogued as rs532688869; called by muse, mutect2, varscan2
- SEC13 | c.960C>T p.N320= (on ENST00000350697 / NM_183352.3; = p.N323= on NM_030673.4) | Silent (SNP) | VAF 77/356 reads (22%) | catalogued as rs141884872; called by muse, mutect2, varscan2
- ZNF577 | c.15G>A p.T5= | Silent (SNP) | VAF 61/313 reads (19%) | catalogued as rs750177133; called by muse, mutect2, varscan2
- IGHV1-58 | chr14:106627248 ins TTGCTCCCGGGGTA | 5'Flank (INS) | VAF 43/304 reads (14%) | called by mutect2, pindel, varscan2
